HCMI case HCM-CSHL-0374-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9166c115-0c9d-4c72-9c2e-da3a3b94072d

Demographics
Sex at birth: male; Year of birth: 1943; Vital status: Dead; Days to death: 13 days; Cause of death: Surgical Complications.

Diagnoses (1)
1. Intraductal papillary-mucinous carcinoma, invasive: ICD-O-3 morphology code: 8453/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 74.7 years (27,272 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 29.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -13 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 13.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 169 cm; BMI: 26.
- Timepoint category: Prior to Diagnosis; Comorbidities: Intraductal Papillary Mucinous Neoplasm; Comorbidity method of diagnosis: Radiology.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Drinker; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0374-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0374-C25-01A-02-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0374-C25-01A-02-S2-HE: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0374-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0374-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 17.
